Somatic mutation profile of tumor specimen TARGET-10-PARETV-09A (aliquot TARGET-10-PARETV-09A-01D) from TARGET case TARGET-10-PARETV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,933 days).
Specimen TARGET-10-PARETV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df7d9153-31d0-469a-87d8-3c2a3c35d5a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARETV-10A (Blood Derived Normal), aliquot TARGET-10-PARETV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a65f22cf-33e3-4ab2-8de9-d75fbc171b2b

The open-access MAF lists 23 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 6, 5'Flank 1, Nonsense Mutation 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RIT1 | c.245T>G p.F82C | Missense Mutation (SNP) | VAF 49/80 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868208063, COSV64170927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.2590C>T p.R864W (on ENST00000357008 / NM_001363606.2; = p.R877W on NM_001273.5) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898273; called by muse, mutect2, varscan2
- L3MBTL4 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs775062263; called by muse, mutect2, varscan2
- MACROD1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs1014451480, COSV55367550; called by muse, mutect2, varscan2
- PIP4K2C | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs376271494; called by muse, mutect2, varscan2
- TTN | c.23840C>T p.P7947L (on ENST00000591111; = p.P7020L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/165 reads (47%) | PolyPhen probably damaging (1); catalogued as rs1235369035; called by muse, mutect2, varscan2
- CYP19A1 | c.723C>A p.Y241* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- DNAH17 | c.5191-8C>G | Splice Region (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.16100C>A p.A5367E | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DCAF12L2 | c.510C>T p.N170= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- DCAF4L1 | c.1104C>T p.F368= | Silent (SNP) | VAF 65/202 reads (32%) | catalogued as rs751949363, COSV60786749; called by muse, mutect2, varscan2
- GJA4 | c.81G>T p.T27= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV60725426; called by muse, mutect2, varscan2
- KCND3 | c.9C>T p.A3= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs777097802; called by muse, mutect2, varscan2
- SLC22A31 | c.441G>A p.P147= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs918550524; called by muse, mutect2
- SLC45A1 | c.1092C>T p.F364= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs764843488, COSV99239065; called by muse, mutect2, varscan2
- APMAP | c.1042-375G>A | Intron (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- BATF2 | c.142-103del | Intron (DEL) | VAF 71/171 reads (42%) | called by mutect2, pindel, varscan2
- BCL11A | c.385+57T>A | Intron (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- DLG2 | c.394-21064G>T | Intron (SNP) | VAF 70/141 reads (50%) | called by muse, mutect2
- DLG2 | c.394-21066C>A | Intron (SNP) | VAF 70/143 reads (49%) | called by muse, mutect2
- HPGDS | c.133+59C>T | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- LINC01619 | chr12:91993159 G>T | 5'Flank (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TRAF4 | c.*192A>C | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
